Somatic mutation profile of tumor specimen TCGA-D8-A1XB-01A (aliquot TCGA-D8-A1XB-01A-11D-A14G-09) from TCGA case TCGA-D8-A1XB, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.9 years (22,976 days).
Specimen TCGA-D8-A1XB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88ec7f55-27f8-4dd7-823b-f7d63ca0f1de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1XB-10A (Blood Derived Normal), aliquot TCGA-D8-A1XB-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f6954f1-d972-4013-973d-905e5e4dd6c1

The open-access MAF lists 34 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 5, In Frame Del 1, Frame Shift Del 1, Nonsense Mutation 1, Nonstop Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD37 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.812); catalogued as COSV52992345; called by muse, mutect2, varscan2
- CBARP | c.373C>T p.R125W (on ENST00000382477; = p.R131W on NM_152769.3) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777794179, COSV53070605; called by muse, mutect2, varscan2
- CFAP74 | c.1933G>A p.V645I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs779154842, COSV54570853; called by muse, mutect2, varscan2
- CLDN14 | c.448C>G p.P150A | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59776045; called by muse, varscan2
- CLEC4A | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57562410; called by muse, mutect2, varscan2
- GLRA3 | c.365T>A p.M122K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV56866486; called by muse, mutect2, varscan2
- GRIPAP1 | c.1314G>A p.M438I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.871); catalogued as COSV64552800; called by muse, mutect2, varscan2
- GSKIP | c.295T>A p.L99I | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV68451409; called by muse, mutect2, varscan2
- INO80 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0.303); catalogued as rs780868252, COSV62738365; called by muse, mutect2, varscan2
- MAP3K1 | c.2369G>T p.R790M | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV68124084, COSV68125666; called by muse, mutect2, varscan2
- MAP3K1 | c.3709T>A p.Y1237N | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68125674; called by muse, mutect2, varscan2
- MFSD11 | c.14C>G p.S5C | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV57974201; called by muse, mutect2, varscan2
- MME | c.1072A>G p.I358V | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.1); catalogued as rs1218024315, COSV100852562; called by muse, mutect2
- OR13G1 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs780930216, COSV62943518; called by muse, mutect2, varscan2
- OR6X1 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs181689044, COSV60009357, COSV60010171; called by muse, mutect2, varscan2
- PKP4 | c.841T>G p.S281A | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as COSV67678450; called by muse, varscan2
- PLK4 | c.1593del p.D532Ifs*6 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | catalogued as COSV54638577; called by mutect2, pindel, varscan2
- PPM1H | c.1271A>G p.Y424C | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs762157400, COSV57377196; called by muse, mutect2, varscan2
- PRRC2C | c.7321G>A p.G2441R (on ENST00000367742; = p.G2439R on NM_015172.4) | Missense Mutation (SNP) | VAF 82/138 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV58909257; called by muse, mutect2, varscan2
- RAPGEF2 | c.2784G>A p.W928* | Nonsense Mutation (SNP) | VAF 15/149 reads (10%) | catalogued as COSV100031713; called by muse, mutect2, varscan2
- SLC6A14 | c.1337T>C p.M446T | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.143); catalogued as rs146124970, COSV100903241; called by muse, mutect2, varscan2
- SPTA1 | c.4780G>A p.E1594K | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV100935654, COSV63750695; called by muse, mutect2
- TANGO2 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs142149828; called by muse, mutect2, varscan2
- TBC1D32 | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51549242; called by muse, mutect2, varscan2
- WTAP | c.485G>C p.R162P | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV61610446, COSV61610540; called by muse, mutect2, varscan2
- ZNF112 | c.2741G>T p.*914Lext*17 (on ENST00000337401 / NM_001083335.2; = p.*908Lext*17 on NM_013380.4 and 2 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV61621381; called by muse, mutect2
- ZNF461 | c.605G>A p.S202N | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV64454477; called by muse, mutect2, varscan2
- PIK3CA | c.314_325del p.V105_R108del | In Frame Del (DEL) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- AC006059.2 | c.1386G>A p.E462= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV59608393; called by muse, mutect2, varscan2
- DCLK3 | c.1635C>T p.I545= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV69363907; called by muse, mutect2, varscan2
- MEIOB | c.1044T>C p.C348= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV58054917; called by muse, mutect2, varscan2
- SLC25A42 | c.546G>T p.G182= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs1162542197, COSV59379651, COSV59381149; called by muse, mutect2, varscan2
- ZNF224 | c.349T>C p.L117= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100425563; called by mutect2, varscan2
- ATP11C | c.*55G>A | 3'UTR (SNP) | VAF 23/261 reads (9%) | catalogued as COSV100558735; called by muse, mutect2
